Gene-level copy-number profile of tumor specimen TCGA-50-7109-01A from TCGA case TCGA-50-7109, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.2 years (21,979 days).
Specimen TCGA-50-7109-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.16ea7d3a-3868-44fc-b546-d6cf83520a6b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-7109-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3fad7a9d-299c-429a-b4a4-167d7719ef6b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,681; copy number 2: 21,394; copy number 3: 23,630; copy number 4: 6,769; copy number 5: 2,285; copy number 6: 1,694; copy number 7: 454; copy number 8: 616; copy number 9: 197; copy number 12: 6; copy number 15: 20; copy number 16: 29; copy number 21: 1; copy number 23: 1; copy number 28: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-7109-01A-11D-2035-01): tumor purity 0.44, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,361 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–147,295,765, 13 genes, copy number 7 (within-gene range 2–7): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L.
- chr1:151,340,640–152,516,008, 60 genes, copy number 9: RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25, CGN, AL365436.3, TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN, FLG-AS1, AL589986.2, HRNR, FLG, FLG2, HMGN3P1, CRNN, LCE5A, CRCT1.
- chr1:154,104,521–155,859,400, 95 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr1:198,949,016–199,080,975, 5 genes, copy number 7 (within-gene range 5–7): AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1.
- chr1:209,900,923–212,414,901, 56 genes, copy number 7 (within-gene range 2–7): SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3, TRAF5, AL590101.1, LINC00467, SNX25P1, ARPC3P2, RD3, AC105275.1, SLC30A1, AC105275.2, AL356310.1, LINC01693, NEK2, FDPSP8, AC096637.2, AC096637.1, LPGAT1, RN7SL344P, Y_RNA, LPGAT1-AS1, AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1, LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1.
- chr1:219,409,039–221,336,489, 42 genes, copy number 7: LYPLAL1-AS1, AL356364.1, ZC3H11B, SLC30A10, RNA5SP76, U3, EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1, LINC02817.
- chr1:224,175,756–225,653,142, 23 genes, copy number 9 (within-gene range 6–9): DEGS1, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, AL391811.1, DNAH14, LBR, LINC02765, AC092811.1, ENAH.
- chr1:226,940,286–226,987,544, 1 gene, copy number 7 (within-gene range 6–7): COQ8A.
- chr1:226,989,865–228,378,876, 50 genes, copy number 7: CDC42BPA, AL353689.2, AL353689.3, AL451047.1, AL627308.1, AL627308.2, AL627308.3, LINC01641, NUCKS1P1, AL606462.1, BTF3P9, AL451054.2, AL451054.3, TUBB8P10, TUBB8P9, AL451054.1, AL451054.4, RNA5SP77, ZNF678, FAM133FP, ZNF847P, SNAP47, JMJD4, SNAP47-AS1, AL731702.1, PRSS38, WNT9A, MIR5008, CICP26, SEPTIN14P17, WNT3A, LINC02809, ARF1, MIR3620, C1orf35, MRPL55, FAM96AP2, AL136379.1, AL359510.2, AL359510.1, GUK1, GJC2, IBA57-DT, IBA57, OBSCN-AS1, OBSCN, AL353593.1, AL353593.2, AL353593.3, AL670729.3.
- chr1:229,022,773–230,436,822, 31 genes, copy number 8: LINC02815, ISCA1P2, LINC02814, AL162595.2, TMEM78, AL162595.1, RAB4A, AL117350.1, CCSAP, RNU6-180P, RN7SKP276, AL160004.2, ACTA1, NUP133, AL160004.1, AL121990.1, ABCB10, RNU4-21P, RNA5SP78, HMGN2P19, TAF5L, URB2, AL354983.1, HMGB1P26, LINC01682, LINC01736, GALNT2, AL136988.2, AL136988.1, PGBD5, AL133516.1.
- chr4:26,070,754–33,693,993, 53 genes, copy number 12–28 (within-gene range 2–28): LINC02357, AC097714.1, RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4, AC024132.2, AC024132.1, LINC02261, Y_RNA, AC024132.3, IGBP1P5, AC007106.2, AC007106.1, AC093791.2, AC093791.1, AC097480.1, AC097480.2, RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1.
- chr4:34,120,090–35,496,003, 7 genes, copy number 15: LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P.
- chr4:36,426,366–36,426,428, 1 gene, copy number 15: MIR1255B1.
- chr4:36,506,043–36,508,869, 1 gene, copy number 15: AC125336.1.
- chr5:30,248,350–31,595,669, 14 genes, copy number 7: HPRT1P2, AC114300.1, AC099517.1, AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P.
- chr5:31,657,218–31,754,656, 7 genes, copy number 7: AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6.
- chr8:36,764,445–40,172,612, 91 genes, copy number 8 (broad region; genes not listed).
- chr8:71,675,300–73,124,088, 24 genes, copy number 8: AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1.
- chr8:74,984,505–118,622,112, 601 genes, copy number 7–12 (broad region; genes not listed).
- chr8:119,873,717–120,050,918, 1 gene, copy number 7 (within-gene range 4–7): DEPTOR.
- chr8:120,052,180–120,373,573, 2 genes, copy number 7 (within-gene range 4–7): AC091563.1, COL14A1.
- chr8:124,920,428–137,425,021, 154 genes, copy number 7 (broad region; genes not listed).
- chr20:52,671,735–54,651,169, 29 genes, copy number 16 (within-gene range 5–16): AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.

Autosomal genes at a single copy (total copy number 1): 1,488. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
